Gene-level copy-number profile of tumor specimen TCGA-F5-6863-01A from TCGA case TCGA-F5-6863, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 71.0 years (25,936 days).
Specimen TCGA-F5-6863-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.f8040c86-4900-4b23-a9c2-a0684ffee370.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F5-6863-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/28d58a46-1be8-41c0-88a5-d49547da8b13

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 5,456; copy number 3: 1,591; copy number 4: 34,529; copy number 5: 2,560; copy number 6: 11,624; copy number 7: 175; copy number 8: 1,029; copy number 9: 1,608; copy number 10: 1,246.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F5-6863-01A-11D-1923-01): tumor purity 0.75, ploidy 2.32, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,854 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,032,892–43,674,591, 81 genes, copy number 9 (broad region; genes not listed).
- chr8:117,794,490–145,066,685, 486 genes, copy number 9 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 9–10 (broad region; genes not listed).
- chr20:30,294,550–64,313,132, 896 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
